Gene-level copy-number profile of tumor specimen C3N-01518-01 from CPTAC case C3N-01518, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.0 years (26,312 days).
Specimen C3N-01518-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0af4a039-b4e6-46c2-93a3-358aa04735b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01518-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/bfcc1511-0f7e-4293-99fd-511399e6df41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 6,398; copy number 2: 48,814; copy number 3: 3,180; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–1): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–73,865, 5 genes, copy number 6 (within-gene range 2–6): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.

Autosomal genes at a single copy (total copy number 1): 4,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
